Somatic mutation profile of tumor specimen 0DI3NF from CCDI case PBBVBH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astroblastoma; Tissue or organ of origin: Cerebrum; Age at diagnosis: 11.7 years (4,261 days).
Specimen 0DI3NF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5631e384-a261-4a34-a2f6-427792296e35.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84441f37-7154-47fe-81cf-896c5aaf6756

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.5803G>A p.G1935S | Missense Mutation (SNP) | VAF 24/705 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308456779, COSV99062192; called by muse, mutect2
- COPS3 | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 285/708 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs138154848; called by muse, mutect2, varscan2
- ARHGEF33 | c.2317A>C p.K773Q | Missense Mutation (SNP) | VAF 128/337 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CREBBP | c.1304del p.N435Mfs*36 | Frame Shift Del (DEL) | VAF 276/799 reads (35%) | called by mutect2, pindel, varscan2
- HFE | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 14/472 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2
- RTL9 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 323/861 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, varscan2
- HMCN1 | c.12414C>T p.V4138= | Silent (SNP) | VAF 74/768 reads (10%) | called by muse, mutect2
- RTL9 | c.864C>G p.T288= | Silent (SNP) | VAF 256/724 reads (35%) | called by muse, varscan2
- SDK2 | c.3606C>A p.G1202= | Silent (SNP) | VAF 112/850 reads (13%) | catalogued as COSV66193157; called by muse, mutect2, varscan2
